Surgical pathology report (de-identified scan), TCGA case TCGA-YL-A8SO, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site PROCURE Biobank, specimen TCGA-YL-A8SO-01B (Primary Tumor).

RADICAL PROSTATECTOMY:

TUMOR PROCUREMENT:

HISTOLOGIC TYPE

ACINAR ADENOCARCINOMA

HISTOLOGIC GRADE (PRIMARY PATTERN+SECONDARY PATTERN = GLEASON SCORE):

4 + 5 = 9

TERTIARY PATTERN NOT PRESENT

PERCENTAGE OF DIFFERENT GLEASON PATTERNS

NOT REPORTED

TUMOR LOCATION

APEX

ANTERIOR

RIGHT

LEFT

POSTERIOR

RIGHT

LEFT

EXTRA-PROSTATIC EXTENSION

PRESENT

NON-FOCAL

SITE OF EXTRA-PROSTATIC EXTENSION

ANTERIOR

RIGHT

LEFT

POSTERIOR

LEFT

SEMINAL VESICAL INVASION

ABSENT

SURGICAL MARGINS

INVOLVED BY INVASIVE CARCINOMA

ANTERIOR

LEFT

NATURE OF POSITIVE MARGINS

NOT REPORTED

EXTENT OF POSITIVE MARGINS

NOT REPORTED

MILLIMETRIC EXTENT OF POSITIVE MARGINS: _NOT REPORTED

GLEASON GRADE OF CARCINOMA PRESENT AT THE POSITIVE MARGINS

NOT REPORTED

LYMPHOVASCULAR INVASION

NOT REPORTED

PERINEURAL INVASION

NOT REPORTED

TUMOR VOLUME

PROPORTION OF PROSTATE INVOLVED BY CARCINOMA: _NOT REPORTED

TREATMENT EFFECT ON CARCINOMA

NOT APPLICABLE

LYMPH NODES

NO LYMPH NODES SUBMITTED

ADDITIONAL PATHOLOGIC FINDINGS

NONE

PATHOLOGICAL STAGING

pT3a

pNX, pMX

ICD-O-3

Adenocarcinoma NOS 8140/3

Site Prostate NOS C61.9

Jan 4/22/14

Source: NCI Genomic Data Commons file 21ef3d98-8530-4303-b4b6-111ed7a3b9ef (TCGA-YL-A8SO.3B555422-C4AD-4FCC-A241-34D33F0DE82B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).